Gene-level copy-number profile of tumor specimen TCGA-DM-A28F-01A from TCGA case TCGA-DM-A28F, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.5 years (26,856 days).
Specimen TCGA-DM-A28F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.23c092fe-16e1-4bff-aff6-0c54e4e88ffa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A28F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c45dd95-8dc0-4685-b165-108634456b07

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,504; copy number 2: 33,972; copy number 3: 17,663; copy number 4: 643; copy number 5: 3,016; copy number 7: 995; copy number 17: 14; copy number 20: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A28F-01A-11D-A16U-01): tumor purity 0.7, ploidy 2.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,037 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–30,075,887, 716 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–69,597,493, 1,298 genes, copy number 5–7 (broad region; genes not listed).
- chr7:85,381,118–86,217,733, 4 genes, copy number 5–7: DYNLL1P7, LINC00972, AC092013.1, SOCS5P1.
- chr8:74,320,613–99,013,743, 372 genes, copy number 5 (broad region; genes not listed).
- chr8:99,527,826–141,195,808, 530 genes, copy number 5 (broad region; genes not listed).
- chr11:131,370,478–132,336,822, 1 gene, copy number 7 (within-gene range 3–7): NTM.
- chr11:131,770,795–133,549,866, 13 genes, copy number 7: AP004372.1, AP000844.2, AP000844.1, NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1.
- chr11:134,945,118–135,075,908, 5 genes, copy number 5: AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr13:23,730,189–23,889,400, 1 gene, copy number 17 (within-gene range 2–17): MIPEP.
- chr13:23,888,842–23,970,188, 4 genes, copy number 17: PCOTH, C1QTNF9B, ANKRD20A19P, AL445985.2.
- chr13:23,979,810–24,035,027, 1 gene, copy number 17: AL445985.1.
- chr13:27,545,913–27,988,693, 12 genes, copy number 20 (within-gene range 3–20): LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD.
- chr13:38,687,077–39,050,109, 8 genes, copy number 17 (within-gene range 3–17): FREM2, RNU6-56P, FREM2-AS1, PLA2G12AP2, ANKRD26P2, STOML3, PROSER1, NHLRC3.
- chr13:52,810,050–54,441,315, 17 genes, copy number 5: MIR759, PPIAP26, PCDH8, OLFM4, LINC01065, AL136359.1, PCDH8P1, AL356295.1, RN7SL618P, AL450423.2, AL450423.1, ZNF646P1, LINC00558, LINC00458, AL356052.1, MIR1297, RPL13AP25.
- chr13:70,923,664–73,661,891, 30 genes, copy number 5: MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr20:15,892,355–62,065,810, 1,025 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,500. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
